Somatic mutation profile of tumor specimen 0DFO18 from CCDI case PBBSED, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 7.2 years (2,640 days).
Specimen 0DFO18: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a171a62c-25ac-4fa9-b4e2-9cd08c008a9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFO13 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbea1068-f95e-40d7-bc72-49a91ad2e5fc

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPAG9 | c.3174C>A p.D1058E (on ENST00000262013 / NM_001130528.3; = p.D1044E on NM_003971.6) | Missense Mutation (SNP) | VAF 48/1010 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2
- SVOPL | c.346-44C>T | Intron (SNP) | VAF 70/204 reads (34%) | catalogued as rs184733768; called by muse, mutect2, varscan2
